Surgical pathology report (de-identified scan), TCGA case TCGA-29-1711, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1711-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Surg Path

[REDACTED]

CLINICAL HISTORY:

Abdominal pelvic swelling, ascites.

CGA-29-1711

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)", received fresh for frozen section is a 376 gram, 10 x 8.5 x 4 cm ovary which was received opened and disrupted from the operating room. There is no recognizable fallopian tube or ovarian tissue and the entire specimen is composed of solid, tan, papillary friable tissue. The serosa is grossly intact where it is recognizable. A representative section was frozen as AF1 and the frozen section remnant is submitted in block A1. Further representative sections are submitted in blocks A2-A8. The serosa is inked blue in block A2.

B. "Uterus, cervix, right tube and ovary", received fresh and placed in formalin is a 204 gram, 12 x 7 x 5.5 cm uterus. The cervix measures 2.5 cm in length and there is a 1 cm patent os. The right ovary measures 3 x 2 x 1.4 cm. and the truncated fallopian tube measures 3 x 0.4 cm; the right tube and ovary are grossly unremarkable on the exterior surface but sectioning of the ovary reveals a 1 x 0.6 x 0.6 cm cavitory area filled with tan papillary tissue which does not extend beyond the ovarian parenchyma. The uterus is grossly unremarkable except for a 2 x 2 x 1 cm tan friable area at the attachment point of the left tube and ovary which does not grossly invade into the myometrium. The soft tissue margin along the cervix and lower uterine segment is inked blue.

BLOCK SUMMARY:

B1-B2- representative sections of tan friable section were left tube and ovary where attached.

B3- representative sections of grossly anterior cervix.

B4- representative sections of grossly unremarkable posterior cervix.

B5-B6- representative sections of grossly unremarkable fallopian tube along with representative sections of sectioned ovary.

B7-B8- full thickness, bisected representative section of posterior endomyometrium with endometrial side in block B7 and serosal side in block B8.

B9-B10- full thickness representative sections of anterior endomyometrium with 1.5 cm intramural leiomyoma.

C. "Left pelvic side wall", received fresh and placed in formalin is a 6 x 4 x 3 cm fragment of brown-tan fibroadipose tissue which consists mostly of tan, friable, papillary tissue. Representative sections are submitted in blocks C1-C2.

D. "Omentum", received fresh and placed in formalin is an 18 x 14 x 7.5 cm aggregate of brown-tan fibroadipose tissue. There are multiple areas throughout which are composed of tan, friable, papillary tissue. Representative sections are submitted in blocks D1-D3.

E. "Tumor nodule left diaphragm", received fresh and placed in formalin is a 5 x 3 x 2.5 cm tan, smooth mass with a small amount of yellow lobulated adipose tissue attached. Sectioning reveals pale tan-red tissue which is completely necrotic. Representative sections are submitted in blocks E1-E3.

F. "Small bowel", received fresh and placed in formalin is an unoriented 11 x 3 cm section of small bowel with a 7 x 6 x 3 cm tan, friable, papillary mass adhered to the serosa. The mass does not penetrate into the mucosa. Representative sections of the mass are submitted in blocks F1-F2. The grossly

[REDACTED]

[page 2 of 3]
uninvolved mucosal margins of the unoriented sections of the bowel are submitted in blocks F3-F4.

G. "Pelvic tumor", received fresh and placed in formalin is a 7 x 5 x 4 cm fragment of unoriented brown-tan fibroadipose tissue with multiple areas of tan, friable, papillary tissue. Representative sections are submitted in blocks G1-G2.

TCGA-29-1711

INTRA OPERATIVE CONSULTATION:

A. "Left tube and ovary": AF1- consistent with papillary serous carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: bilateral salpingo-oophorectomy, hysterectomy and partial small bowel resection.

PATHOLOGIC STAGE (AJCC 6th Edition): pT3C pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation by the [REDACTED]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "LEFT TUBE AND OVARY (AF1)" (OOPHORECTOMY):

TYPE: PAPILLARY SEROUS ADENOCARCINOMA OF THE OVARY.

FIGO GRADE: 2

TUMOR SIZE: 10 X 8.5 X 4 CM.

WEIGHT: 376 GRAMS

SEROSA: UNINVOLVED, SEE ABOVE DESCRIPTION.

ADDITIONAL FINDINGS: FALLOPIAN TUBE NOT IDENTIFIED.

B. "UTERUS, CERVIX, RIGHT TUBE, AND OVARY":

RIGHT OVARY:

PAPILLARY SEROUS ADENOCARCINOMA.

SEROSAL SURFACE NEGATIVE FOR TUMOR.

MAXIMUM TUMOR SIZE: 1 CM

FALLOPIAN TUBE: NEGATIVE FOR TUMOR.

UTERUS, 204 GRAMS

ENDOMETRIUM: PROLIFERATIVE

MYOMETRIUM: LEIOMYOMATA

CERVIX: NO PATHOLOGIC DIAGNOSIS

SEROSA: POSITIVE FOR PAPILLARY SEROUS ADENOCARCINOMA (TUMOR SIZE ABOUT 2 CM)

SPECIMEN MARGINS: NEGATIVE FOR TUMOR

C. "LEFT PELVIC SIDE WALL":

PAPILLARY SEROUS ADENOCARCINOMA.

D. "OMENTUM" (PARTIAL RESECTION):

[page 3 of 3]
PAPILLARY SEROUS ADENOCARCINOMA.

E. "TUMOR NODULE LEFT DIAPHRAGM":

PAPILLARY SEROUS ADENOCARCINOMA.

TCGA-29-1711

F. "SMALL BOWEL" (PARTIAL RESECTION):

SMALL INTESTINE WITH SEROSAL PAPILLARY SEROUS ADENOCARCINOMA.
MAXIMUM TUMOR SIZE: ABOUT 7 CM
MUCOSAL MARGINS NEGATIVE FOR TUMOR.

G. "PELVIC TUMOR":

PAPILLARY SEROUS ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1528b1e5-560f-417b-8471-7743621bb71e (TCGA-29-1711.E0E207A0-C3C2-4BFC-9D7D-D00C5C953D3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).